Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-8003, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-8003-01A (Primary Tumor).

[page 1 of 4]
Path Report

Final

SURGICAL PATHOLOGY REPORT

ACCESSION NO. [REDACTED]

Final Diagnosis(es):

(A) Lymph node, pericaval, biopsy: One lymph node negative for metastatic malignancy (0/1).

(B) Lymph node, hepatic artery, biopsy: One lymph node negative for metastatic malignancy (0/1).

(C) Bile duct margin, biopsy: Negative for malignancy.

(D) Pancreas margin, biopsy: Negative for malignancy.

(E) Antrum, duodenum, head of pancreas, common bile duct, and proximal jejunum, Whipple:

Ductal adenocarcinoma, pancreatic, moderately differentiated, pT3N1MX (see synoptic report).

Synoptic Report:

Specimen: Head of pancreas.

Procedure: Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy.

Tumor Site: Pancreatic head.

Tumor Size:

Greatest Dimension: 2.8 cm.

Additional Dimensions: 1.8 x 2.2 cm.

Histologic Type: Ductal adenocarcinoma.

Histologic Grade: G2: Moderately differentiated.

Microscopic Tumor Extension: Tumor invades duodenal wall.

Margins: Margins uninvolved by invasive carcinoma

Lymphovascular Invasion: Present.

Perineural Invasion: Present.

Pathologic Staging:

Primary Tumor: pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery.

Regional Lymph Nodes: pN1. Regional lymph node metastasis.

Number of Lymph Nodes Examined: 12

Number of Lymph Nodes Involved: 1

Additional Pathologic Findings: Chronic pancreatitis.

' The gross description and all microscopic slides have been reviewed and interpreted by the undersigned pathologist'

Specimen(s) Received:

A: Peri caval lymph node

B: hepatic artery lymph node

C: Bile duct margin

D: Pancreas margin

[page 2 of 4]
E: Antrum, duodenum, head of pancreas, common bile duct, and proximal jejunum

Clinical History:

Adenocarcinoma of the head of pancreas.

(C) Stitch marks marginal.

Intraoperative Consultation:

FSA1: Pericaval lymph node: No carcinoma (1 block).

FSB1-FSB2: Hepatic artery lymph node: No carcinoma (2 blocks).

FSC1: Bile duct margin: No carcinoma (1 block).

FSD1: Pancreatic margin: No carcinoma (1 block).

Gross Description:

(A) (pericaval lymph node) Received fresh for frozen section evaluation of metastatic disease is a 0.8 x 0.5 x 0.3 cm, red-yellow, fatty tissue fragment. The specimen is bisected and submitted in toto in cassette FSA1.

(B) (hepatic artery lymph node) Received fresh for frozen section evaluation of metastatic disease is a 2.0 x 0.8 x 0.5 cm, tan, rubbery lymph node. The specimen is bisected and submitted in toto in cassettes FSB1 and FSB2.

(C) (bile duct margin) Received fresh for frozen section evaluation for margins is a 1.2 x 1.0 x 0.4 cm, tan-red, donut shaped tissue fragment. The specimen is submitted in toto in FSC1.

(D) (pancreas margin) Received fresh for frozen section evaluation for margins is a 2.0 x 1.2 x 0.5 cm, tan-red, fragment of pancreas. The specimen is submitted in toto in FSD1.

(E) (antrum, duodenum, head of pancreas, common bile duct and proximal jejunum)

Received fresh and subsequently placed in formalin after sections were taken for Tumor Bank are a previously opened antrum of stomach (13.3 x 5.7 x 0.3 cm wall thickness), duodenum (21.5 x 7.1 x 0.7 cm wall thickness), pancreas (5.3 x 2.7 x 2.4 cm), bile duct (5.0 cm in length by 1.0 cm in diameter), and gallbladder (9.3 x 2.7 x 1.7 cm). The posterior aspect of the pancreas has been inked black, the anterior yellow, uncinate margin green, vascular notch margin purple, and pancreatic duct margin red. The bile duct is opened longitudinally revealing dilatation of the bile duct. A longitudinal section through the bile duct and duodenum reveal no gross invasion of pancreatic tumor into the ampulla or duodenum. Sectioning through the pancreas reveals a firm, tan lesion within the head of the pancreas that measures 1.8 x 2.2 x 2.8 cm. The tumor appears to be invading into the duodenal wall but not into the duodenal

[page 4 of 4]
Unless otherwise stated in the report, all tissue tested for ERPR by IHC, Her2 by IHC and/or HER2 by FISH have been fixed as per ANP.22998 for a minimum of 6 hours and a maximum of 48 hours.

ER, PR, Ki-67, p53 are reported as a semi-quantitative percentage of positively stained nuclei. Her-2/neu and EGFR are scored as follows: No staining at all is scored as (0), weak, incomplete membrane staining in any proportion of cells is scored as (1+), less than strong but complete staining in any proportion of cells or complete strong staining in less than 30% of cells is scored as (2+), and strong complete staining in more than 30% of cells is scored as (3+). All studies are performed on tissue fixed in 10% neutral buffered formalin and embedded in paraffin unless otherwise stated in the report.

Source: NCI Genomic Data Commons file 6b3e420a-e0a3-4d30-b7a8-c064bf42f8c3 (TCGA-HZ-8003.6A1D0A0E-CA8E-4243-9700-F738B073407C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).